Surgical pathology report (de-identified scan), TCGA case TCGA-20-1687, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1687-01A (Primary Tumor).

[page 1 of 4]
TCGA-20-1687

Age:

Sex:

Clinical History/Diagnosis: H/O breast cancer with pelvic mass.

Source of Specimen(s):

- 1: Cytology -no fee code
- 2: Left Fallopian Tube +/- Ovary
- 3: Right Fallopian Tube +/- Ovary
- 4: Uterus with Cervix
- 5: Mesenteric nodule
- 6: Omentum
- 7: Small bowel nodule
- 8: Anterior abdominal wall Peritoneum, biopsy
- 9: Colon, sigmoid and donuts
- 10: Appendix

Gross Description:

Received in ten parts.

Source of tissue: 1. Cytology.

Source of tissue: 2. Labeled #2, "left tube and ovary"

Gross Description: Received fresh labeled " patient name and medical number, left tube and ovary" consists of a 65 gram, 5.9 x 5 x 3.3 cm tan-pink hemorrhagic ovarian mass with a 5.5 x 0.5 cm red-tan hemorrhagic fallopian tube with fimbriated end. The mass is inked black and sectioned to reveal a tan papillary mass involving approximately 95% of the ovary. The mass does not grossly appear to invade the wall. Multiple cysts ranging from 1 cm up to 3 cm are filled with a yellow thickened material. Sectioning of the fallopian tube reveals tan mildly hemorrhagic cut surfaces with a pinpoint lumen. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 2A bisected fimbriated end and cross sections of fallopian tube. 2B-2D random ovarian tumor.

Source of tissue: 3. Labeled #3, "right tube and ovary"

Intraoperative Consultation: CARCINOMA PRESENT FAVOR OVARIAN PRIMARY PSAMMA BODIES AND PAPILLARY CANCER.

Gross Description: Received fresh labeled " patient name and medical number, right tube and ovary" consists of a 79 gram, 7.5 x 4.5 x 4 cm tan-pink hemorrhagic ovarian mass with a 5 x 0.5 cm red-tan hemorrhagic fallopian tube with fimbriated end. The mass is inked black and sectioned to reveal

[page 2 of 4]
a tan papillary mass involving approximately 95% of the ovary. A piece of the mass is frozen and submitted in cassette 3FS for microscopic evaluation. The tumor grossly appears to invade the wall. Sectioning of the fallopian tube reveals tan hemorrhagic cut surfaces with a pinpoint lumen. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 3FS frozen section. 3A - bisected fimbriated end and cross sections of fallopian tube. 3B-3D random ovarian tumor.

Source of tissue: 4. Labeled #4, "uterus, cervix and uterosacral ligaments"

Gross Description: Received fresh labeled " patient name and medical number, uterus, cervix and uterosacral ligaments" consists of a 124 gram, 6 x 5.2 x 4 cm red-tan hemorrhagic uterus with attached cervix 3 x 2.6 cm. The exocervix is tan-pink hemorrhagic and smooth with a 0.5 cm patent os. There is a 3.5 x 3 x 2 cm firm nodule on the anterior surface. The nodule is inked black, the specimen is opened to reveal a tan-pink mildly trabeculated endocervix, a tan-pink hemorrhagic myometrium averaging 2.4 cm and a tan-pink mildly hemorrhagic endometrium averaging 0.1 cm. The specimen is sectioned and the mass on the anterior surface appears to involve the myometrium. The remainder of the cut surface is tan-pink trabeculated and hemorrhagic. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 4A right uterosacral ligament. 4B left uterosacral ligament. 4C anterior cervix. 4D posterior cervix. 4E anterior full thickness. 4F anterior full thickness with tumor. 4G tumor. 4H posterior full thickness.

Source of tissue: 5. Labeled #5, "mesenteric nodules"

Gross Description: Received fresh labeled " patient name and medical number, mesenteric nodules" consists of two 1 x 0.7 x 0.2 cm tan nodules. Entirely submitted in cassette 5A for microscopic evaluation.

Source of tissue: 6. Labeled #6, "omentum"

Gross Description: Received fresh labeled " patient name and medical number, omentum" consists of a 15 x 6 x 2 cm aggregate of hemorrhagic omentum. Multiple masses are grossly identified ranging from 2 cm up to 3 cm. Representative sections are submitted in cassettes 6A-6E for microscopic evaluation.

Source of tissue: 7. Labeled #7, "small bowel nodule"

[page 3 of 4]
Gross Description: Received fresh labeled " patient name and medical number, small bowel nodule" consists of a 2 x 1.5 x 0.7 cm tan-red hemorrhagic nodule.

Entirely submitted in cassette 7A for microscopic evaluation.

Source of tissue: 8. Labeled #8, "anterior abdominal wall peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, anterior abdominal wall peritoneum" consists of a 2 x 1 x 0.2 cm portion of hemorrhagic fat. Entirely submitted in cassette 8A for microscopic evaluation.

Source of tissue: 9. Labeled #9, "sigmoid colon and donut"

Gross Description: Received fresh labeled " patient name and medical number, sigmoid colon and donut" consists of a 13 cm in length portion of red hemorrhagic with attached fat. One margin is opened and the opposite margin is sutured. There is a 2.5 x 2.5 cm firm mass located 0.7 cm from the open margin. The open margin is inked black and the specimen is opened to reveal a tan-red hemorrhagic mucosa with flattened transverse folds. No lymph nodes are grossly identified. Also received in the same container are two donuts measuring 3 x 3 x 0.3 cm and 1.5 x 1.3 x 0.3 cm. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 9A-9B donuts (9A contains the larger donut). 9C staple margin. 9D-9F perpendicular sections of open margin in relation to tumor mass. 9G-9H random colon. 9I-9M fat.

Source of tissue: 10. Labeled #10, "appendix"

Gross Description: Received fresh labeled " patient name and medical number, appendix" consists of a 4.5 x 0.3 cm tan-red hemorrhagic appendix with attached mesoappendix. Multiple firm nodules are grossly identified at the distal end of the specimen. Sectioning reveals a wall thickness averaging 0.1 cm, a pinpoint lumen and a velvety mucosa. The entire specimen is submitted for microscopic evaluation.

Designation of Sections: 10A proximal distal ends. 10B remainder of specimen.

Final Diagnosis:

1. Cytology.

2. Left fallopian tube and ovary; salpingo-oophorectomy:

- High grade serous carcinoma involving ovary (5.9 cm); carcinoma is

[page 4 of 4]
present on ovarian surface.

- Fallopian tube with no tumor seen.

3. Right fallopian tube and ovary; salpingo-oophorectomy:

- High grade serous carcinoma involving ovary (7.5 cm) and paratubal soft tissue; carcinoma is present on ovarian surface.

- Angiolymphatic invasion is identified.

4. Uterus, cervix and uterosacral ligaments; hysterectomy:

- High grade serous carcinoma involving uterine serosa and myometrium (multifocal), parametrial soft tissue and left periuterosacral ligament adipose tissue.

- Extensive angiolymphatic invasion is identified in the myometrium.

- Inactive endometrium.

5. Mesenteric nodules, excision:

- Serous carcinoma.

6. Omentum, excision:

- Serous carcinoma.

7. Small bowel nodule, excision:

- Serous carcinoma.

8. Anterior abdominal wall peritoneum, excision:

- Serous carcinoma.

9. Sigmoid colon and donut, excision:

- Serous carcinoma (2.5 cm) involving colonic serosa, serosa and pericolic adipose tissue; carcinoma extends to the open end of the specimen.

- Donuts negative for carcinoma.

- Four lymph nodes with no tumor seen, (0/4).

10. Appendix, appendectomy:

- Serous carcinoma present on serosal surface.

- Fibrous obliteration of appendix.

Source: NCI Genomic Data Commons file b97f328c-a55a-41d4-bda1-2efaa2dc4e2f (TCGA-20-1687.E966D90F-0E5F-42E6-B487-1F10FBEF204F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).